MMRF case MMRF_1710 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/bdf1bd48-33cb-4414-881c-2ad90a67823c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 48 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 48.3 years (17,639 days); ISS stage: I; Days to last known disease status: 796 days (2.2 years); Days to last follow up: 796 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 235 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 253 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 580 days (1.6 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 618 days (1.7 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 796.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 1): M Protein 0.82 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 93.5 mg/dL; Immunoglobulin G 16.9 g/L; Immunoglobulin A 1.49 g/L; Immunoglobulin M 0.87 g/L; Beta 2 Microglobulin 1.84 µg/mL; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 7.4 g/dL; Glucose 4.13 mmol/L; C-Reactive Protein 0.27 mg/dL.
- Day 98 (ECOG 1): M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.2 mg/dL; Immunoglobulin G 6.59 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 3.3 mmol/L.
- Day 174 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.611 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.22 mg/dL; Immunoglobulin G 7.66 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 1.41 µg/mL; Lactate Dehydrogenase 5.23 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 33 g/L; Total Protein 6.1 g/dL; Glucose 3.8 mmol/L.
- Day 260 (ECOG 0): M Protein 0.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.004 mg/dL; Immunoglobulin G 7.33 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.46 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 33 g/L; Total Protein 6 g/dL; Glucose 4.35 mmol/L.
- Day 405 (ECOG 0): M Protein 0.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.8 mg/dL; Immunoglobulin G 7.6 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 4.4 mmol/L.
- Day 476: Serum Free Immunoglobulin Light Chain, Kappa 0.81 mg/dL; Immunoglobulin G 9.04 g/L; Immunoglobulin A 1.14 g/L; Immunoglobulin M 0.56 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 4.35 mmol/L.
- Day 580 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.019 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.29 mg/dL; Beta 2 Microglobulin 1.83 µg/mL; Hemoglobin 8.25 mmol/L; Leukocytes 4.32 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 5.17 mmol/L.
- Day 713 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.81 mg/dL; Immunoglobulin G 7.39 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 1.68 µg/mL; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 5.9 g/dL; Glucose 4.24 mmol/L.

Other clinical attributes
- Day -7: Weight: 82 kg; Height: 162 cm.

Biospecimens (2 samples)
- Sample MMRF_1710_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_1710_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
